Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94A, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94A-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O.3
Mixed germ cell tumor 9085/3
Site @ Testis C62.9
Op 3/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

1. "Left orchiectomy":

- Mixed germ cell tumor: immature teratoma (9%), embryonal carcinoma (40%), seminoma (25%), endodermal sinus tumor (25%) and choriocarcinoma (1%).
- Size of lesion: approximately 8cm.
- Angiolymphatic invasion: not detected.
- Margin of surgical resection (spermatic cord): uninvolved by neoplasia.
- Epididymis, rete testis, spermatic cord, tunica albuginea and tunica vaginalis uninvolved by neoplasia.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Testis, NOS	Mixed germ cell tumor	pT1

Criteria	W 11/2/14	Yes	No
Dual, Synchronous Primary Noted			✓

Source: NCI Genomic Data Commons file 2d2b96f2-a998-4398-bc6a-c8f0ef1f56e4 (TCGA-YU-A94A-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).